MMRF case MMRF_1531 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/09f98283-4505-4077-9e1c-b1d26f773a2c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Dead; Days to death: 520 days (1.4 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.0 years (23,360 days); ISS stage: III; Days to last known disease status: 520 days (1.4 years); Days to last follow up: 520 days (1.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 524 days (1.4 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 520.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -12 (ECOG 1): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 298 mg/dL; Immunoglobulin G 31 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.56 g/L; Beta 2 Microglobulin 5.9 µg/mL; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 9.7 ×10⁹/L; Absolute Neutrophil 6.5 ×10⁹/L; Platelets 88 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.25 mmol/L; Albumin 32 g/L; Total Protein 6.7 g/dL; Glucose 4.24 mmol/L.
- Day 64 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 2.46 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 4.4 µg/mL; Lactate Dehydrogenase 3.77 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 1.95 mmol/L; Albumin 32 g/L; Total Protein 4.8 g/dL; Glucose 5.12 mmol/L.
- Day 171 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.46 mg/dL; Immunoglobulin G 5.04 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.65 g/L; Beta 2 Microglobulin 3.7 µg/mL; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 11.3 ×10⁹/L; Absolute Neutrophil 7.1 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 125 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 5.6 g/dL; Glucose 5.06 mmol/L.
- Day 255 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.882 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.37 mg/dL; Immunoglobulin G 3.49 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 3.3 µg/mL; Lactate Dehydrogenase 3.57 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 10.3 ×10⁹/L; Absolute Neutrophil 8.4 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 5.3 g/dL; Glucose 4.57 mmol/L.
- Day 346 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.911 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.54 mg/dL; Immunoglobulin G 3.43 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 10 ×10⁹/L; Absolute Neutrophil 6.6 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 5.2 g/dL; Glucose 5.61 mmol/L.
- Day 444 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.7 mg/dL; Immunoglobulin G 3.75 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.6 µg/mL; Lactate Dehydrogenase 3.8 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 9.6 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 5.3 g/dL; Glucose 5.17 mmol/L.
- Day 514 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14.7 mg/dL; Immunoglobulin G 3.39 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 3.4 µg/mL; Lactate Dehydrogenase 4.8 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 21.3 ×10⁹/L; Absolute Neutrophil 19.5 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 5.5 g/dL; Glucose 5.72 mmol/L.

Other clinical attributes
- Day -12: Weight: 84 kg; Height: 185 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1531_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_1531_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
